Gene-level copy-number profile of tumor specimen TCGA-ZF-AA4V-01A from TCGA case TCGA-ZF-AA4V, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 66.9 years (24,448 days).
Specimen TCGA-ZF-AA4V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2e1abb90-b6bd-4124-9802-401d82a7bfb4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA4V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fae67a97-b362-4c33-a8e5-465a7a7547db

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 3,515; copy number 2: 30,963; copy number 3: 17,138; copy number 4: 5,459; copy number 5: 1,000; copy number 6: 885; copy number 7: 102; copy number 8: 237; copy number 9: 29; copy number 10: 44; copy number 11: 156; copy number 12: 7; copy number 15: 3; copy number 18: 2; copy number 20: 134; copy number 22: 23; copy number 23: 49; copy number 24: 4; copy number 28: 18; copy number 32: 27; copy number 33: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA4V-01A-11D-A38F-01): tumor purity 0.64, ploidy 2.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:82,101,460–82,212,830, 3 genes (within-gene range 0–3): CCDC57, AC129510.1, AC129510.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,732 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–152,580,516, 371 genes, copy number 5–24 (broad region; genes not listed).
- chr1:152,622,834–152,860,985, 19 genes, copy number 22: LCE3A, LCEP4, LCEP3, LCE2D, LCE2C, LCE2B, LCE2A, LCE4A, C1orf68, LCEP2, LCEP1, KPRP, LCE1F, LCE1E, LCE1C, LCE1B, LCE1A, LCE6A, AL162596.1.
- chr1:158,999,968–161,631,963, 134 genes, copy number 20 (broad region; genes not listed).
- chr2:30,887,626–31,580,938, 10 genes, copy number 6: AC009301.1, GALNT14, AC009305.1, CAPN14, RNA5SP90, EHD3, AL121657.1, XDH, SRD5A2, AL133247.1.
- chr3:84,638,405–87,226,277, 19 genes, copy number 5: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795.
- chr5:58,198–2,262,023, 79 genes, copy number 15–32 (broad region; genes not listed).
- chr5:36,035,021–36,876,700, 18 genes, copy number 5–8: UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT.
- chr5:36,885,206–36,886,497, 1 gene, copy number 5: KRT18P31.
- chr5:44,716,193–45,895,970, 11 genes, copy number 5: RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:1,623,806–8,343,139, 143 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr6:8,341,937–8,435,561, 2 genes, copy number 5: AL359378.1, SLC35B3.
- chr8:124,550,784–131,712,980, 95 genes, copy number 6–11 (within-gene range 2–11) (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 6 (broad region; genes not listed).
- chr12:67,265,842–69,959,097, 69 genes, copy number 5–33 (broad region; genes not listed).
- chr12:69,946,543–69,947,081, 1 gene, copy number 18: AC078922.1.
- chr16:6,703,883–35,197,544, 944 genes, copy number 5–22 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 2–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr20:31,303,212–31,952,046, 35 genes, copy number 6–10: DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1.
- chr20:31,970,181–31,970,831, 1 gene, copy number 10: AL031658.2.

Autosomal genes at a single copy (total copy number 1): 3,255. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
